Gene-level copy-number profile of tumor specimen TCGA-09-2044-01B from TCGA case TCGA-09-2044, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 77.3 years (28,231 days).
Specimen TCGA-09-2044-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.a399002a-41d4-4159-b13b-a3d13a44617e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-09-2044-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cd49d8d4-b9aa-4822-b092-56173d9e4520

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 63; copy number 1: 20,959; copy number 2: 30,385; copy number 3: 6,018; copy number 4: 1,689; copy number 5: 285; copy number 6: 77; copy number 7: 328.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-09-2044-01B-01D-0704-01): tumor purity 0.89, ploidy 1.88, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 43 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:69,739,464–69,968,336, 1 gene (within-gene range 0–1): MITF.
- chr6:131,469,059–131,469,536, 1 gene: RPL21P67.
- chr15:55,611,544–56,918,571, 27 genes (within-gene range 0–2): PRTG, AC012378.1, AC009997.1, NEDD4, CNOT6LP1, RN7SL568P, CD24P2, RFX7, AC084783.1, TEX9, AC068726.1, RNU6-1287P, HMGB1P33, AC084782.1, AC084782.2, MNS1, AC084782.3, AC090518.1, ZNF280D, Y_RNA, AC090517.4, AC090517.2, AC090517.3, AC090517.5, AC090517.1, AC010999.2, AC010999.1.
- chr16:7,004,007–7,614,992, 5 genes: RNU6-328P, AC022206.1, AC007222.2, AC007222.1, AC005774.2.
- chr16:78,981,722–79,229,453, 9 genes: AC027279.3, AC027279.2, AC009145.4, AC009145.3, AC009145.1, AC009145.2, AC092376.2, AC092376.3, AC092376.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 690 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:108,958,248–113,515,187, 77 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr5:58,198–6,533,200, 127 genes, copy number 5 (broad region; genes not listed).
- chr5:17,684,584–30,693,984, 114 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr6:139,271,362–139,667,284, 1 gene, copy number 5 (within-gene range 4–5): AL592429.2.
- chr6:139,435,636–141,636,503, 19 genes, copy number 5: LINC01625, ATP5PBP6, AL390205.1, FILNC1, AL050338.1, AL050338.2, AL357146.1, RNA5SP220, MIR3668, AL035446.2, MIR4465, RPS3AP24, AL035446.1, AL357084.1, AL357080.1, AL355596.2, AL355596.1, RN7SKP106, RPS3AP23.
- chr12:66,767–911,452, 22 genes, copy number 5 (within-gene range 3–5): IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P.
- chr15:25,580,969–25,581,122, 1 gene, copy number 5: AC023449.1.
- chr15:25,738,508–25,738,620, 1 gene, copy number 5: RNA5SP390.
- chr16:7,726,841–20,489,659, 328 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 18,789. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
